Gene-level copy-number profile of tumor specimen ALCH-AEKD-TTP1-A from ALCHEMIST case ALCH-AEKD, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenosquamous carcinoma; Age at diagnosis: 66.3 years (24,223 days).
Specimen ALCH-AEKD-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b642ae57-9fe9-4243-b38d-10acebdca652.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEKD-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/e0206b30-af5f-4949-ae4e-b6ec554f93eb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 3,427; copy number 2: 53,900; copy number 3: 1,040; copy number 4: 14; copy number 5: 7; copy number 8: 2; copy number 11: 1; copy number 17: 1.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:62,332,487–62,332,557, 1 gene (within-gene range 0–2): MIR4758.
- chr22:41,909,554–41,947,152, 4 genes: SHISA8, TNFRSF13C, MIR378I, CENPM.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 11 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:65,189,995–65,323,015, 6 genes, copy number 5: BMS1P12, AL512605.1, AL512605.2, IGKV1OR9-1, FOXD4L5, CBWD4P.
- chr21:43,140,523–43,141,092, 1 gene, copy number 17: FRGCA.
- chr21:43,414,483–43,479,534, 4 genes, copy number 5–11: SIK1, LINC00319, LINC00313, AP001048.1.

Autosomal genes at a single copy (total copy number 1): 2,552. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
